Somatic mutation profile of tumor specimen TCGA-FD-A5C1-01A (aliquot TCGA-FD-A5C1-01A-11D-A289-08) from TCGA case TCGA-FD-A5C1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 61.6 years (22,505 days).
Specimen TCGA-FD-A5C1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1aa7b60-dab6-4389-8f0e-d34088a25b84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A5C1-10A (Blood Derived Normal), aliquot TCGA-FD-A5C1-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c93f9ec6-5385-4513-affc-69d32985cbb0

The open-access MAF lists 150 somatic variants for this specimen: 114 protein-altering or splice-affecting, 31 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 31, Nonsense Mutation 11, Splice Site 3, RNA 3, In Frame Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 12/79 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.5329C>T p.R1777W | Missense Mutation (SNP) | VAF 38/537 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.761); catalogued as rs770329105, CM115978, COSV56356498; ClinVar: pathogenic; called by muse, mutect2
- ABCB6 | c.2219C>T p.T740I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54694920; called by muse, mutect2, varscan2
- AFF4 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV54793696; called by muse, mutect2, varscan2
- AFF4 | c.1529G>A p.G510D | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.229); catalogued as rs770559857, COSV54793710; called by muse, mutect2, varscan2
- AMACR | c.976C>A p.R326S | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.071); catalogued as COSV56871112; called by muse, mutect2, varscan2
- ANK3 | c.7894G>C p.E2632Q | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV55053233; called by muse, mutect2, varscan2
- ANK3 | c.2548G>T p.E850* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV99783173; called by muse, mutect2
- ARHGAP4 | c.1143G>C p.K381N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV63131652; called by muse, mutect2, varscan2
- ARID1A | c.4336C>T p.R1446* | Nonsense Mutation (SNP) | VAF 17/132 reads (13%) | catalogued as COSV61370903, COSV61383151; called by muse, mutect2, varscan2
- ARMCX2 | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.345); catalogued as rs1030550437, COSV57529740; called by muse, mutect2, varscan2
- ASB15 | c.772T>A p.C258S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.241); catalogued as COSV51925376; called by muse, mutect2, varscan2
- ASNSD1 | c.994T>A p.S332T | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53623484; called by muse, mutect2, varscan2
- ATP2B4 | c.2644A>G p.M882V | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58176576; called by muse, mutect2
- ATP5MC2 | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV58601219; called by muse, mutect2, varscan2
- BEST1 | c.68G>A p.C23Y | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV57120421; called by muse, mutect2
- C8orf82 | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1210935548, COSV52768993; called by muse, mutect2, varscan2
- CALCR | c.781C>T p.H261Y (on ENST00000649521 / NM_001164737.2; = p.H245Y on NM_001742.4) | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs975291322, COSV64007364; called by muse, mutect2, varscan2
- CAP2 | c.301-1G>A p.X101_splice | Splice Site (SNP) | VAF 30/91 reads (33%) | catalogued as rs1211643756, COSV57731336, COSV57734109; called by muse, mutect2, varscan2
- CD28 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV60730462; called by muse, mutect2
- CDH10 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV52577588, COSV52600832; called by muse, mutect2, varscan2
- CDH7 | c.981+1G>A p.X327_splice | Splice Site (SNP) | VAF 6/50 reads (12%) | catalogued as COSV59884458; called by muse, mutect2, varscan2
- CDKN1A | c.153_154insTAA p.F51_D52ins* | Nonsense Mutation (INS) | VAF 25/67 reads (37%) | catalogued as COSV99781780; called by mutect2, pindel, varscan2
- CEBPZ | c.3123G>C p.K1041N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV52205847; called by muse, mutect2, varscan2
- CPS1 | c.3706A>G p.I1236V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.916); catalogued as rs767193495, COSV51807434; called by muse, mutect2, varscan2
- CRNN | c.1451G>A p.R484K | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV55121600; called by muse, mutect2
- CST8 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as COSV55670866; called by muse, mutect2
- CYP2R1 | c.200G>C p.R67T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV100585028; called by muse, mutect2
- CYP46A1 | c.1023C>A p.Y341* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99952969; called by muse, mutect2, varscan2
- DENND2A | c.2911G>C p.G971R | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52050169, COSV52057210; called by muse, mutect2, varscan2
- DGKI | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.691); catalogued as rs148415050; called by muse, mutect2, varscan2
- DHX8 | c.2467C>T p.R823* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as rs1443174800, COSV52257028; called by muse, mutect2, varscan2
- DMXL2 | c.6076G>C p.E2026Q | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV51844416; called by muse, mutect2
- DNAH2 | c.10808C>T p.A3603V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs759666638, COSV66717794, COSV66718529; called by muse, mutect2, varscan2
- DST | c.7513G>C p.V2505L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as COSV55008729, COSV99761051; called by muse, mutect2, varscan2
- EFCAB5 | c.2300T>A p.M767K | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1373151383, COSV100300990; called by muse, mutect2
- ELAVL4 | c.892T>C p.C298R | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63915461; called by muse, mutect2
- ENAH | c.1283C>G p.T428R | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV52867089; called by muse, mutect2, varscan2
- EXTL1 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as rs781198382, COSV65337157; called by mutect2, varscan2
- FAM120B | c.1543A>G p.I515V | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs1402962770, COSV53003023; called by muse, mutect2, varscan2
- FAM90A1 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.848); catalogued as COSV56711477, COSV56712227; called by muse, mutect2, varscan2
- FLG | c.6760G>C p.E2254Q | Missense Mutation (SNP) | VAF 193/487 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.341); catalogued as rs1474952901, COSV64240252; called by muse, varscan2
- GABBR1 | c.2753C>T p.S918F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV63541970; called by muse, mutect2, varscan2
- GABRA4 | c.274-1G>T p.X92_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | catalogued as COSV51926017; called by muse, mutect2
- GEN1 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV58056232; called by muse, mutect2, varscan2
- HERC6 | c.605C>A p.S202* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV52033853, COSV99910726; called by muse, mutect2, varscan2
- HGF | c.1598G>T p.R533L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs771437724, COSV55947930; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs772506887, COSV57131925; called by muse, mutect2
- IMPG2 | c.3142C>T p.R1048W | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs770293441, COSV51976584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INO80 | c.3645G>C p.Q1215H | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62737399; called by muse, mutect2, varscan2
- KRT83 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV53339534; called by muse, mutect2
- LMOD1 | c.1798C>T p.Q600* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100939308; called by muse, mutect2, varscan2
- MAN2C1 | c.481A>G p.M161V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV99145980; called by muse, mutect2, varscan2
- MAST4 | c.6250G>A p.E2084K (on ENST00000403625 / NM_001164664.2; = p.E1895K on NM_015183.3) | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.024); catalogued as rs554102328, COSV55121883; called by muse, mutect2, varscan2
- ME3 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529462870, COSV60164215, COSV60165192; called by muse, mutect2, varscan2
- MEI1 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100300519; called by muse, mutect2, varscan2
- MGAT4B | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.376); catalogued as rs754559279, COSV52977520; called by muse, mutect2, varscan2
- MMS19 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs200904065; called by muse, mutect2, varscan2
- MZF1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs958860070, COSV99285523; called by muse, mutect2
- NLRP13 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV61621187; called by muse, mutect2, varscan2
- NLRX1 | c.2360C>G p.S787C | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV52703421; called by muse, mutect2, varscan2
- NPC1 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as rs144973225, CM022224; called by muse, mutect2, varscan2
- NUMA1 | c.2212G>C p.E738Q | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as COSV61184717; called by muse, mutect2, varscan2
- OR4A15 | c.888G>C p.M296I | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.034); catalogued as COSV59034725; called by muse, mutect2
- OR4K5 | c.609T>G p.S203R | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60003123; called by muse, mutect2, varscan2
- OR51S1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs560546339, COSV59057342; called by muse, mutect2
- OR5M11 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV101602080, COSV73142022; called by muse, mutect2
- ORC6 | c.296G>C p.R99T | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV54478130; called by muse, mutect2
- OTOP2 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1392190825, COSV58881494; called by muse, mutect2, varscan2
- PANK2 | c.1385G>C p.G462A (on ENST00000316562 / NM_153638.3; = p.G171A on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV57253816; called by muse, mutect2, varscan2
- PANK3 | c.550C>G p.P184A | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs902838984, COSV53322740; called by muse, mutect2, varscan2
- PCDHGB2 | c.2329G>A p.A777T | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV53929412; called by muse, mutect2, varscan2
- PDCD4 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1430624093, COSV54522459; called by muse, mutect2, varscan2
- PDCD5 | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs752278730, COSV55678209; called by muse, mutect2, varscan2
- PGAP3 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54092818; called by muse, mutect2
- PLEKHH2 | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1452249965, COSV56752176; called by muse, mutect2, varscan2
- PLGRKT | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV56349783; called by muse, mutect2, varscan2
- POU4F3 | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); catalogued as COSV57943108; called by muse, varscan2
- PPM1A | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV57786404; called by muse, mutect2
- PPP2R1A | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV59043676; called by muse, mutect2, varscan2
- QRICH1 | c.1753C>G p.L585V | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.709); catalogued as COSV62615135; called by muse, mutect2, varscan2
- RBM46 | c.1585C>G p.Q529E | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.585); catalogued as COSV55978223; called by muse, mutect2, varscan2
- ROCK1 | c.1898C>G p.S633C | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV101296662; called by muse, mutect2
- SAMD13 | c.187G>A p.V63M (on ENST00000370671; = p.V57M on NM_001010971.3) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as rs770412773, COSV65744868; called by muse, mutect2, varscan2
- SETD1A | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs150802841, COSV52686797; called by muse, mutect2, varscan2
- SH3BP5 | c.1243A>C p.K415Q | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.021); catalogued as COSV53743757; called by muse, mutect2
- SLC12A5 | c.578G>A p.R193K (on ENST00000454036 / NM_001134771.2; = p.R170K on NM_020708.5) | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54791839; called by muse, mutect2, varscan2
- SLC35E3 | c.101G>C p.W34S | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99972178; called by muse, mutect2
- STAM2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55730264, COSV55730606; called by muse, mutect2, varscan2
- TAS2R41 | c.713C>A p.S238Y | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV68764978, COSV68765160; called by muse, mutect2, varscan2
- THEM5 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 99/203 reads (49%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV64312840; called by muse, mutect2, varscan2
- THUMPD1 | c.836C>G p.S279* | Nonsense Mutation (SNP) | VAF 12/147 reads (8%) | catalogued as COSV101189729; called by muse, mutect2
- TNRC6C | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56943478, COSV56944879; called by muse, mutect2, varscan2
- TOX3 | c.1347G>T p.Q449H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV54865283; called by muse, mutect2
- TRIM9 | c.1282C>T p.Q428* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100032525, COSV53616109; called by muse, mutect2
- TRRAP | c.7378G>A p.E2460K (on ENST00000359863 / NM_001244580.1; = p.E2442K on NM_003496.3) | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs752243631, COSV62838509; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1945G>A p.V649M | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV54649353; called by muse, mutect2, varscan2
- UGT1A10 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60836260; called by muse, mutect2
- UPF3A | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV60894808; called by muse, mutect2, varscan2
- VPS37D | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61446420; called by muse, mutect2, varscan2
- WARS1 | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs985886508, COSV59925187; called by muse, mutect2, varscan2
- XKR6 | c.1760T>C p.I587T | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs756429215, COSV58655483; called by muse, mutect2, varscan2
- YWHAH | c.378G>T p.M126I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV50708289; called by muse, mutect2, varscan2
- ZBTB22 | c.1241G>C p.R414P | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV56468345; called by muse, mutect2, varscan2
- ZC3H13 | c.257G>C p.R86T | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV54451742; called by muse, mutect2, varscan2
- ZMYM4 | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV58909204; called by muse, mutect2, varscan2
- ZNF106 | c.3775G>A p.E1259K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV55515646; called by muse, mutect2, varscan2
- ZNF479 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV58637685; called by muse, mutect2, varscan2
- ZNF653 | c.1538A>G p.N513S | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1173492023, COSV53402573; called by muse, mutect2, varscan2
- ZSWIM5 | c.2179G>C p.E727Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV100655318, COSV62733831; called by muse, mutect2, varscan2
- ZXDB | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV66492328; called by muse, mutect2
- CTR9 | c.926_928del p.C309del | In Frame Del (DEL) | VAF 12/31 reads (39%) | called by pindel, varscan2
- PRAMEF19 | c.1221G>C p.L407F | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF26 | c.1411A>G p.I471V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- AP4B1 | c.1269G>A p.L423= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs752709249, COSV56724411; called by muse, mutect2
- ARHGEF25 | c.1251G>T p.L417= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs1187011409, COSV54085880; called by muse, mutect2, varscan2
- ARSA | c.759G>A p.L253= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs1249616269, COSV53350273; called by muse, mutect2, varscan2
- ASMTL | c.24G>A p.G8= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV67243390; called by muse, mutect2, varscan2
- ASPHD1 | c.276C>G p.L92= | Silent (SNP) | VAF 59/189 reads (31%) | catalogued as COSV100435708, COSV58098789; called by muse, mutect2, varscan2
- ASPHD1 | c.780C>T p.C260= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV58098791; called by muse, mutect2, varscan2
- BOP1 | c.126C>G p.L42= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV56639329, COSV56640330; called by muse, mutect2, varscan2
- CENPN | c.843G>A p.G281= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV59904933; called by muse, mutect2
- COG4 | c.306C>T p.I102= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV60422150; called by muse, mutect2, varscan2
- DCC | c.2286T>C p.Y762= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV59097339; called by muse, mutect2, varscan2
- DLGAP2 | c.3167G>A p.*1056= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs755053043, COSV101423103; called by muse, mutect2, varscan2
- DUS3L | c.1200C>T p.L400= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs777464888, COSV57831686; called by muse, mutect2, varscan2
- INMT | c.330G>A p.A110= | Silent (SNP) | VAF 17/228 reads (7%) | catalogued as rs185075033, COSV50000081; called by muse, mutect2
- IQCN | c.2916C>T p.L972= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV62747415, COSV62748671; called by muse, mutect2, varscan2
- MAG | c.1200G>A p.Q400= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV62700077; called by muse, mutect2, varscan2
- MROH7 | c.3690G>A p.E1230= | Silent (SNP) | VAF 49/156 reads (31%) | catalogued as rs1277969001, COSV64886927; called by muse, mutect2, varscan2
- NALCN | c.4791G>C p.L1597= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as rs1359102386, COSV51929345; called by muse, mutect2
- PCDH8 | c.1464C>T p.G488= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1452500047, COSV58812067; called by muse, mutect2, varscan2
- PKD1L1 | c.6480C>G p.G2160= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV56962747; called by muse, mutect2, varscan2
- POLQ | c.5376G>A p.G1792= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV51749701, COSV51755692; called by muse, mutect2, varscan2
- RORA | c.456G>A p.Q152= (on ENST00000335670 / NM_134261.3; = p.Q177= on NM_002943.3) | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs143671650; called by muse, mutect2, varscan2
- SLC6A7 | c.411C>T p.I137= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as rs1177082338, COSV57937742, COSV57937754; called by muse, mutect2, varscan2
- SPEG | c.9495C>T p.D3165= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs56175079; called by muse, mutect2, varscan2
- TCN1 | c.849T>C p.N283= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV57252894; called by muse, mutect2
- TMEM187 | c.669C>A p.L223= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as COSV64141478; called by muse, mutect2
- TMPRSS13 | c.1584C>T p.V528= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV70626153; called by muse, mutect2, varscan2
- TRIM58 | c.993A>G p.T331= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV63569830; called by muse, mutect2
- TRPV4 | c.2106C>T p.Y702= | Silent (SNP) | VAF 36/198 reads (18%) | catalogued as rs373961067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSPOAP1 | c.1230C>A p.L410= | Silent (SNP) | VAF 69/154 reads (45%) | catalogued as COSV52107004; called by muse, mutect2, varscan2
- ZFPM1 | c.2832G>A p.P944= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100128868; called by muse, mutect2, varscan2
- ZSCAN31 | c.285C>T p.L95= | Silent (SNP) | VAF 22/400 reads (6%) | catalogued as COSV60180672; called by muse, mutect2
- ADCY4 | c.*1G>C | 3'UTR (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100156953; called by muse, mutect2, varscan2
- MIR542 | n.23T>C | RNA (SNP) | VAF 17/129 reads (13%) | called by muse, mutect2, varscan2
- SNORD114-9 | n.54C>G | RNA (SNP) | VAF 36/185 reads (19%) | called by muse, mutect2, varscan2
- SNORD115-8 | n.75T>G | RNA (SNP) | VAF 24/339 reads (7%) | called by muse, mutect2
- ZNF211 | c.90+459G>A | Intron (SNP) | VAF 5/44 reads (11%) | catalogued as rs769369443, COSV53741353; called by mutect2, varscan2
